CCDI case PBCCGN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e322de69-bd84-4ed9-86cc-3a953cc5c478

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.9 years (7,284 days).

Biospecimens (3 samples)
- Sample 0DOLUQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOLVA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DOLVU: Tissue type: Tumor; Specimen type: Solid Tissue.
